Surgical pathology report (de-identified scan), TCGA case TCGA-10-0933, project TCGA-OV (Ovarian Serous Cystadenocarcinoma), tissue source site MD Anderson Cancer Center, specimen TCGA-10-0933-01A (Primary Tumor).

[page 1 of 2]
- [REDACTED]
- (A) RIGHT OVARY AND FALLOPIAN TUBE:
HIGH GRADE OVARIAN CARCINOMA WITH MIXED COMPONENTS. (SEE COMMENT)
Fallopian tube, no tumor present.
- (B) LEFT OVARY AND FALLOPIAN TUBE:
METASTATIC HIGH GRADE CARCINOMA CONSISTENT WITH OVARIAN PRIMARY INVOLVING THE
FALLOPIAN TUBE.
Ovary, no tumor present.
- (C) UTERUS AND CERVIX:
Cervix, no tumor present.
Complex endometrial hyperplasia with atypia.
Endometrial polyp.
Myometrial leiomyomata.
- (D) CUL-DE-SAC TUMOR NODULE:
METASTATIC HIGH GRADE CARCINOMA CONSISTENT WITH OVARIAN PRIMARY.
- (E) LEFT PELVIC LYMPH NODE:
One lymph node, no tumor present.
- (F) OMENTAL BIOPSY;
METASTATIC HIGH GRADE CARCINOMA CONSISTENT WITH OVARIAN PRIMARY.
- [REDACTED]

COMMENT

The ovarian tumor measures 13.0 cm in maximum dimension. It has various patterns including serous, undifferentiated, endometrioid, mucinous, and sarcomatoid. Keratin immunohistochemical stains are positive in the sarcomatoid areas.

[REDACTED]

GROSS DESCRIPTION

(A) RIGHT TUBE AND OVARY - An ovary (13.0 x 13.0 x 7.0 cm) and attached unremarkable fallopian tube (5.0 cm in length and 0.2 cm in circumference). The ovary is completely replaced by a variegated solid tumor containing areas of necrosis (90%) admixed with a small portion of solid tan-white firm area (5%) and soft tan-pink tissue (5%). Normal ovarian parenchyma is not identified. Representative sections of the tumor are submitted for frozen section diagnosis. Additional sections are submitted for permanent.

SECTION CODE: A1-A5, tumor; (FS diagnosis); A6-A26, tumor representative sections (firmer white area and pink); A27, A28 fallopian tube; A29, tumor, representative section of the necrotic area. [REDACTED]

*FS/DX: OVARY WITH HIGH GRADE CARCINOMA. [REDACTED]

(B) LEFT TUBE AND OVARY - An unremarkable ovary (1.9 x 1.0 x 0.5 cm) and attached fallopian tube (7.0 cm in length and 0.2 cm in circumference). A 2.0 x 2.0 cm solid tan-white tumor is present in the fallopian tube. The tumor appears to arise within the fallopian tube.

SECTION CODE: B1, representative section from fallopian tube tumor for frozen section; B2-B5, sequential sections of fallopian tube from fimbriated end to more normal end near the attachment with ovary; B6, grossly normal ovary in its entirety.

[REDACTED]
*FS/DX: FALLOPIAN TUBE WITH HIGH-GRADE CARCINOMA. [REDACTED]

[page 2 of 2]
[REDACTED]

(C) UTERUS, CERVIX – A uterus including the cervix, 10.5 x 6.5 x 3.5 cm. The serosa is pink-tan and glistening. The endometrium is pink-tan, 0.3 to 0.4 cm in thickness and is diffusely studded with cysts 0.1 to 0.2 cm in diameter and filled with clear fluid. In the posterior endometrium, the endometrium is polypoid, measuring 0.7 cm in thickness. A 1.0 cm nodule with gray-tan, firm consistency and whorled cut surface is present in the lower part of uterus. The myometrium is otherwise devoid of any lesion. The cervix has multiple Nabothian cysts.

INK CODE: Blue, anterior surface of uterus; black, posterior surface of uterus.

[REDACTED]

(D) COL-DE-SAC TUMOR NODULE - Multiple tan-pink irregular fragments of tissue measuring 1.0 x 0.4 x 0.3 cm in aggregate. Total in D. [REDACTED]

(E) LEFT PELVIC LYMPH NODE - A single lymph node measuring 1.0 x 0.8 x 0.3 cm. The specimen is bisected and entirely submitted in E. [REDACTED]

(F) OMENTAL BIOPSY - An irregular fragment of adipose tissue measuring 30.0 x 8.0 x 0.5 cm. The specimen is serially sectioned. One possible lymph node is identified measuring 0.5 x 0.5 x 0.3 cm. However, no lesions grossly identified.

SECTION CODE: F1, one possible lymph node; F2-F15, representative sections. [REDACTED]

CLINICAL HISTORY

Ovarian carcinoma, presumed

[REDACTED]

-----END OF REPORT-----

[REDACTED]

Source: NCI Genomic Data Commons file ee85335e-ac62-4373-aac2-177dba3f7f73 (TCGA-10-0933.F973309D-55DD-489B-A7CA-9348666A9129.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).